Surgical pathology report (de-identified scan), TCGA case TCGA-5T-A9QA, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Holy Cross, specimen TCGA-5T-A9QA-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT **FINAL**

Procedure Date:

Accession Date:

CLINICAL DATA: breast mass

IOC/FROZEN:

A1FS: Infiltrating carcinoma.

Received at reported at

GROSS EXAMINATION:

A. "Left Breast Mass, One Stitch Lateral, Two Stitches Anterior (Frozen Section)". The specimen is received fresh for frozen section designated "Left Breast Mass, One Stitch Lateral, Two Stitches Anterior"

and consists of a 9.5 x 6.3 x 4.0 cm portion of tan-yellow fibroadipose tissue. The posterior margin is inked black and the anterior margin is inked blue. Sectioning shows a 3.4 x 2.8 x 2.5 cm solid ill-defined tan-white infiltrating mass which extends very close to the anterior and posterior inked margins.

Representative sections are submitted in twelve cassettes. A1FS- frozen section remnant; A2-A4- mass and posterior margin; A5, A6- mass and anterior margin; A7- inferior margin; A8- superior margin; A9, A10- medial margin; A11, A12- lateral margin.

Placed in formalin:

Removed from formalin:

Fixation time: 56 hours and 5 minutes

B. "Left Breast Mass (B), One Stitch Lateral, Two Stitch Anterior". The specimen is received in formalin designated "Left Breast Mass (B), One Stitch Lateral, Two Stitch Anterior" and consists of a 6.8 x

4.2 x 2.7 cm portion of tan-yellow fibroadipose tissue with sutures as described. The lateral margin is inked black, the medial margin is inked blue, the superior margin is inked yellow, and the inferior margin is inked orange and the posterior margin is inked green. Sectioning shows an ill-defined area of grey-white induration measuring

approximately 2.0 x 1.5 x 1.5 cm located in the posterior portion of the specimen, and extending close to the

inferior, lateral and medial margins. The remaining specimen is composed primarily of pale yellow lobular adipose

tissue. Representative sections are submitted in fourteen cassettes. B1-B6- ill-defined area of induration with

lateral, medial and inferior margins; B7, B8- posterior margin; B9- B11- superior margin; B12- anterior margin;

B13, B14- additional sections of breast tissue with lateral and medial margins.

Placed in formalin:

Removed from formalin:

SURGICAL PATHOLOGY REPORT **FINAL**

Fixation time: 7 hours and 20minutes

ICD - 0 - 3

carcinoma, infiltrating duct and
mucinous (mixed w other types,
infiltrating duct.)

8523/3

Site: breast, NOS c50.9

hw
11/20/14

[page 2 of 2]
C. "Skin Tags". The specimen is received in formalin designated "Skin Tags" and consists of multiple grey-brown skin fragments measuring up to 0.5 cm. Submitted in toto in one cassette.

Placed in formalin:

Removed from formalin:

Fixation time: 7 hours and 20 minutes

DIAGNOSIS:

A. Left breast mass, excision:

Infiltrating ductal carcinoma of the breast; see synoptic report.

B. Left breast mass:

Few microscopic foci of atypical ductal hyperplasia, with marked fibrocystic changes.

Residual carcinoma is not identified.

C. Skin tags:

Skin tags, benign.

SYNOPTIC REPORT: INFILTRATING BREAST CANCER

Procedure: Excision without wire-guided localization

Lymph Node Sampling: Not performed

Specimen Laterality: Left

Histologic Type of Invasive Carcinoma: Invasive ductal carcinoma with areas of mucinous differentiation

Tumor Size: 3.4 cm in greatest diameter

Histologic Grade:

Glandular/Tubular Differentiation: 3

Mitotic Rate: 3

Nuclear Pleomorphism: 3

Overall Grade: 3 of 3

Tumor Focality: Single focus of invasive carcinoma

Ductal Carcinoma In Situ

Few foci of ductal carcinoma in situ present; extensive intraductal component not identified

Margins:

Deep surgical margin: Positive for invasive carcinoma (one low power field)

Anterior surgical margin: Negative for infiltrating carcinoma (infiltrating carcinoma reaches within 0.5 mm of

the anterior surgical margin, in two low power fields)

Lymph Nodes: Not submitted

Lymph-Vascular Space Invasion: Present

SURGICAL PATHOLOGY REPORT

FINAL

Pathologic Staging:

Primary Tumor: pT2

Regional Lymph Nodes: pNX

Distant Metastasis: Not Applicable

COMMENT:

Prognostic markers are pending; a supplemental report will follow.

CPT Code: 88307 x 2 , 88305, 88331

*Per ISS - mucinous component is 50%
should be categorized as 'other' -
mucinous / ductal.*

Source: NCI Genomic Data Commons file a59ab1a1-133c-4fc8-90e8-c2eeab079a41 (TCGA-5T-A9QA.2DB5519B-B36D-4616-94F3-601A01185F22.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).